Gene-level copy-number profile of tumor specimen TCGA-ZJ-AAXB-01A from TCGA case TCGA-ZJ-AAXB, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, endocervical type; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB2; Tumor grade: G3; Age at diagnosis: 42.4 years (15,492 days).
Specimen TCGA-ZJ-AAXB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.9e635f83-63fd-4e94-96ae-9105cd1f6005.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-ZJ-AAXB-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/276c418e-61a2-449a-a506-663ea8eceec1

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 934; copy number 2: 24,156; copy number 3: 18,835; copy number 4: 10,047; copy number 5: 4,362; copy number 6: 1,035; copy number 7: 432; copy number 8: 14.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-ZJ-AAXB-01A-11D-A42N-01): tumor purity 0.77, ploidy 2.9, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5,843 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:49,202,126–49,451,896, 1 gene, copy number 5 (within-gene range 4–5): AC009975.2.
- chr2:49,563,388–52,961,452, 28 genes, copy number 5: AC009971.1, RPL7P13, SNORA75, NRXN1, AC068725.1, MTCO1P42, AC009234.1, MIR8485, AC007560.1, AC007682.1, AC007402.1, AC007402.2, KNOP1P3, CRYGGP, AC097463.1, CCDC12P1, AC079304.1, ZNF863P, Y_RNA, LINC01867, GGCTP3, AC139712.1, CRTC1P1, FTH1P6, MIR4431, AC010967.1, AC010967.2, AC010967.3.
- chr3:93,843,764–198,222,513, 1,800 genes, copy number 5–6 (broad region; genes not listed).
- chr5:58,198–45,895,970, 710 genes, copy number 6–7 (broad region; genes not listed).
- chr7:140,084,746–140,176,983, 1 gene, copy number 5 (within-gene range 2–5): KDM7A.
- chr7:140,177,184–141,052,409, 24 genes, copy number 5: KDM7A-DT, RNU6-797P, RNU1-58P, AC005377.1, PPP1R2P6, SLC37A3, RNA5SP247, RNA5SP248, RAB19, AC069335.1, MKRN1, DENND2A, Y_RNA, AC006452.1, RN7SL771P, ADCK2, NDUFB2, NDUFB2-AS1, BRAF, RNU6-85P, AC006006.1, CCT4P1, MRPS33, RNU4-74P.
- chr7:142,111,749–142,753,076, 70 genes, copy number 5 (broad region; genes not listed).
- chr7:142,760,415–142,763,943, 1 gene, copy number 5 (within-gene range 4–5): PRSS3P1.
- chr7:152,590,641–154,894,285, 20 genes, copy number 6 (within-gene range 4–6): AC104843.2, 5S_rRNA, AC104843.1, AC003109.1, XRCC2, ATP5PBP3, RN7SL845P, ACTR3B, AC006348.1, AC079809.1, LINC01287, AC073236.1, PAXBP1P1, AC005998.1, DPP6, AC005588.1, AC006019.3, AC006019.1, AC006019.2, AC024730.1.
- chr7:155,962,632–157,016,426, 15 genes, copy number 7: AC021218.1, Y_RNA, AC093813.1, LINC01006, LINC00244, AC005534.1, RNF32, RNF32-AS1, LMBR1, RNU4-31P, AC006357.1, NOM1, MNX1, MNX1-AS2, MNX1-AS1.
- chr10:53,291,072–55,746,908, 15 genes, copy number 6–7: AC036101.1, RNA5SP318, AL365496.1, PCDH15, RNU6-687P, AL353784.1, NEFMP1, MIR548F1, AC051618.1, AC016822.1, AL355314.1, AL355314.2, MTRNR2L5, GAPDHP21, AC069545.1.
- chr14:90,366,697–90,816,479, 14 genes, copy number 8: RPL21P11, AL512791.2, CALM1, AL512791.1, LINC02317, LINC00642, AL096869.3, TTC7B, AL096869.1, AL096869.2, AL139193.1, AL139193.2, AL122020.2, AL122020.1.
- chr19:27,638,483–58,605,223, 1,686 genes, copy number 5 (broad region; genes not listed).
- chr20:87,250–64,313,132, 1,458 genes, copy number 5–6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 934. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
